Somatic mutation profile of tumor specimen C3L-01283-01 (aliquot CPT0079380009) from CPTAC case C3L-01283, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 37.0 years (13,526 days).
Specimen C3L-01283-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4be7286e-0b64-4319-a004-483cc3dd88c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01283-31 (Blood Derived Normal), aliquot CPT0080120001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe6bb051-4677-404b-aceb-a5f0d5b247b1

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 2, Nonsense Mutation 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1007dup p.Y336* | Nonsense Mutation (INS) | VAF 41/212 reads (19%) | hotspot (GDC flag); catalogued as CI983205; called by mutect2, pindel, varscan2
- DUSP21 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs766627568, COSV59133782; called by muse, mutect2, varscan2
- HDHD3 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as COSV53056648; called by muse, mutect2, varscan2
- PTPRC | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs368551275; called by muse, mutect2
- SLC45A2 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 55/496 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV56869752; called by muse, mutect2, varscan2
- ARMC9 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2
- BAHD1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); called by muse, mutect2
- BRCA1 | c.3371T>A p.F1124Y | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- CNOT1 | c.2149A>G p.M717V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE6 | c.537T>A p.Y179* | Nonsense Mutation (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- ECPAS | c.4745T>C p.L1582P | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT1 | c.5824A>C p.T1942P | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- FLII | c.328-13_348del p.X110_splice | Splice Site (DEL) | VAF 16/215 reads (7%) | called by mutect2, pindel
- GGT5 | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- IMP3 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KYNU | c.1332C>G p.F444L | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PCDHGC3 | c.1871A>G p.H624R | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC32A1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SPACA9 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF599 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BAHD1 | c.273G>A p.E91= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- FCRL3 | c.960C>T p.F320= | Silent (SNP) | VAF 45/427 reads (11%) | catalogued as COSV63840269; called by muse, mutect2, varscan2
- SKAP2 | c.-2G>T | 5'UTR (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
